Somatic mutation profile of tumor specimen TCGA-KL-8338-01A (aliquot TCGA-KL-8338-01A-11D-2310-10) from TCGA case TCGA-KL-8338, project TCGA-KICH (Kidney Chromophobe). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 51.1 years (18,667 days).
Specimen TCGA-KL-8338-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2dbf2e51-cf9c-446d-9dc4-b97ebf40e22b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KL-8338-11A (Solid Tissue Normal), aliquot TCGA-KL-8338-11A-01D-2310-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7af03a2f-ae40-4a4b-bd68-2dfcf1238b2c

The open-access MAF lists 18 somatic variants for this specimen: 13 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 12, Silent 5, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.824G>A p.C275Y | Missense Mutation (SNP) | VAF 22/29 reads (76%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs863224451, CM076568, CM951234, COSV52661919, COSV52663595, COSV52675710, COSV52772708; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AFF2 | c.1192C>T p.P398S | Missense Mutation (SNP) | VAF 34/262 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.191); catalogued as rs1195148696, COSV99664213; called by muse, mutect2, varscan2
- ANKRD17 | c.5234G>T p.G1745V | Missense Mutation (SNP) | VAF 29/148 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100429273, COSV58218660; called by muse, mutect2, varscan2
- CACNA1G | c.1382G>A p.R461Q | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.474); catalogued as rs747761042, COSV100661882; called by muse, mutect2, varscan2
- CXCL5 | c.274C>A p.L92I | Missense Mutation (SNP) | VAF 19/197 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99932904; called by muse, mutect2, varscan2
- DHX36 | c.371A>T p.Y124F | Missense Mutation (SNP) | VAF 76/190 reads (40%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV100273627; called by muse, mutect2, varscan2
- KNL1 | c.6458C>T p.T2153M (on ENST00000346991 / NM_170589.5; = p.T2127M on NM_144508.5) | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs1382368782, COSV100706546; called by muse, mutect2, varscan2
- MICOS13 | c.103G>T p.D35Y | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.71); catalogued as COSV56799234; called by muse, mutect2, varscan2
- MIER3 | c.699A>C p.K233N | Missense Mutation (SNP) | VAF 25/329 reads (8%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.81); catalogued as COSV100423546; called by muse, mutect2
- NDUFB5 | c.449+2T>C p.X150_splice | Splice Site (SNP) | VAF 16/41 reads (39%) | catalogued as COSV99372561; called by muse, mutect2, varscan2
- PIKFYVE | c.4141A>G p.S1381G | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV100010807; called by muse, varscan2
- RNF103 | c.1343A>T p.N448I | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV52894148; called by muse, mutect2
- SPATA5L1 | c.1759C>A p.L587I | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.888); catalogued as COSV59745565; called by muse, mutect2, varscan2
- IGKV1-9 | c.18C>T p.P6= | Silent (SNP) | VAF 13/102 reads (13%) | catalogued as rs569206745; called by muse, mutect2, varscan2
- TMEM150B | c.690G>A p.P230= | Silent (SNP) | VAF 33/77 reads (43%) | catalogued as rs929546497, COSV100442359; called by muse, mutect2, varscan2
- VCAN | c.9348G>T p.V3116= | Silent (SNP) | VAF 53/147 reads (36%) | catalogued as COSV54113980; called by muse, mutect2, varscan2
- XKR7 | c.654C>T p.Y218= | Silent (SNP) | VAF 6/69 reads (9%) | catalogued as COSV101629261; called by muse, mutect2
- ZBTB40 | c.2577C>T p.T859= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as rs1436507050, COSV65144752; called by muse, mutect2, varscan2
